Somatic mutation profile of tumor specimen TCGA-BP-4164-01A (aliquot TCGA-BP-4164-01A-02D-1386-10) from TCGA case TCGA-BP-4164, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 51.7 years (18,898 days).
Specimen TCGA-BP-4164-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4d2150e-5550-47cc-8da1-fbcd3c36d6ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4164-11A (Solid Tissue Normal), aliquot TCGA-BP-4164-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27e285d0-5380-4731-ad44-0063fccdb7ac

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 29, Silent 12, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TPSD1 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs3865205, COSV52973780; called by muse, varscan2
- CACNA2D1 | c.2351G>A p.G784E (on ENST00000356253 / NM_001366867.1; = p.G772E on NM_000722.4) | Missense Mutation (SNP) | VAF 127/355 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.115); catalogued as COSV62373270; called by muse, varscan2
- CD28 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1371617402, COSV60730055; called by muse, mutect2, varscan2
- COG5 | c.1735G>A p.V579M (on ENST00000347053 / NM_001379512.1; = p.V600M on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 147/407 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.519); catalogued as COSV51743212; called by muse, mutect2, varscan2
- DDI1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs753910078, COSV56369141; called by muse, mutect2, varscan2
- DEFB115 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 190/455 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV68722966; called by muse, mutect2, varscan2
- DIP2A | c.2609G>A p.S870N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59472716; called by muse, mutect2, varscan2
- DST | c.16129A>G p.N5377D (on ENST00000361203 / NM_001374722.1; = p.N2965D on NM_015548.5) | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV54999208; called by muse, mutect2, varscan2
- EXOSC9 | c.588T>A p.F196L | Missense Mutation (SNP) | VAF 128/510 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV54664943, COSV54665451; called by muse, mutect2, varscan2
- JADE3 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 80/882 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54464432, COSV99510161; called by muse, mutect2
- KCND3 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1332646922, COSV56175522; called by muse, mutect2
- KMT2C | c.9943C>T p.Q3315* | Nonsense Mutation (SNP) | VAF 193/507 reads (38%) | catalogued as COSV51310208; called by muse, mutect2, varscan2
- MMP21 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 86/111 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as COSV64288730; called by muse, mutect2, varscan2
- MYH1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs1361044268, COSV55432071, COSV55436433; called by muse, mutect2, varscan2
- NYAP2 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1349573850, COSV55998979; called by muse, mutect2, varscan2
- NYNRIN | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs764502613, COSV66841222; called by muse, mutect2, varscan2
- OR52I2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57044289, COSV57044778; called by muse, mutect2, varscan2
- OTOP2 | c.85C>G p.R29G | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV58880701; called by muse, mutect2, varscan2
- PBRM1 | c.4708C>T p.Q1570* (on ENST00000296302 / NM_001366071.2; = p.Q1463* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 140/213 reads (66%) | catalogued as COSV56262255; called by muse, mutect2, varscan2
- PKHD1L1 | c.2619G>A p.M873I | Missense Mutation (SNP) | VAF 164/465 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV65737670; called by muse, mutect2, varscan2
- S100PBP | c.567T>G p.N189K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV63139750; called by muse, mutect2, varscan2
- S1PR4 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755185881, COSV55739513; called by muse, varscan2
- SPTBN5 | c.8209C>G p.Q2737E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV58016760; called by muse, mutect2
- SUCLG1 | c.850T>G p.S284A | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.089); catalogued as COSV67264695; called by muse, mutect2, varscan2
- TAFA2 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69172720; called by muse, varscan2
- TAZ | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV54795874; called by muse, mutect2, varscan2
- TBC1D8B | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 209/502 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52176169; called by muse, mutect2, varscan2
- TEKT3 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as rs1348482180, COSV58626015; called by muse, mutect2
- TGIF2LX | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as COSV52213373; called by muse, mutect2, varscan2
- TP53BP2 | c.2618C>T p.P873L (on ENST00000343537 / NM_001031685.3; = p.P744L on NM_005426.2) | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59066550; called by muse, mutect2, varscan2
- USP7 | c.710A>C p.Q237P | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV61213085; called by muse, mutect2, varscan2
- VHL | c.525C>A p.Y175* | Nonsense Mutation (SNP) | VAF 84/111 reads (76%) | catalogued as CD071418, CM024001, CM961437, COSV56543727, COSV56544133; called by muse, mutect2, varscan2
- PRKCH | c.701_702del p.K234Nfs*43 | Frame Shift Del (DEL) | VAF 43/403 reads (11%) | called by mutect2, pindel, varscan2
- RPS21 | c.242+2_242+5del p.X81_splice | Splice Site (DEL) | VAF 76/351 reads (22%) | called by pindel, varscan2*
- AUTS2 | c.3054C>T p.P1018= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV61384640; called by muse, mutect2
- C1orf116 | c.6C>G p.P2= | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as COSV63943763; called by muse, mutect2, varscan2
- DHX8 | c.1632G>T p.G544= | Silent (SNP) | VAF 85/218 reads (39%) | catalogued as COSV52251069; called by muse, mutect2, varscan2
- DIO2 | c.570T>C p.D190= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV70444790, COSV70446851; called by muse, mutect2, varscan2
- EFS | c.1269G>A p.G423= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs905362305, COSV53731221; called by muse, varscan2
- ENAM | c.39T>G p.P13= | Silent (SNP) | VAF 115/517 reads (22%) | catalogued as COSV68535271; called by muse, mutect2, varscan2
- INSR | c.432C>T p.V144= | Silent (SNP) | VAF 9/189 reads (5%) | catalogued as COSV57158054; called by muse, mutect2
- LRRC8B | c.1278T>C p.L426= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV58373179; called by muse, mutect2, varscan2
- LTF | c.2127G>A p.R709= | Silent (SNP) | VAF 134/180 reads (74%) | catalogued as COSV51605784; called by muse, varscan2
- OR4D5 | c.264C>T p.G88= | Silent (SNP) | VAF 39/298 reads (13%) | catalogued as COSV58305727; called by muse, mutect2, varscan2
- POSTN | c.468C>T p.N156= | Silent (SNP) | VAF 154/329 reads (47%) | catalogued as rs368300503; called by muse, mutect2, varscan2
- SNTB1 | c.273C>G p.V91= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1367434418, COSV67324628; called by muse, mutect2, varscan2
